Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5270, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5270-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, left frontal tumor, excision: Grade 3 (of 4) oligoastrocytoma, in progression from a grade 2 oligodendroglioma, (see comment).

The tumor forms a rim of a "solid highly cellular" tumor, 0.4 cm in thickness as well as infiltrates surrounding parenchyma in a single cell fashion.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 1.01. The 1p to 1q probe ratio was 1.03. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

There was no evidence of deletion of 1p and 19q. However, approximately 60% of the cells had 3-4 copies of the 1p, 1q, 19p, and 19q probes. Similar results have been observed in other glioma specimens with gain of chromosomes 1 and 19. The results may also be consistent with tumor tetraploidy or aneuploidy.

This test was developed and its performance characteristics determined by Laboratory and Medicine and [REDACTED]. It has not been cleared or approved by the USFDA, and is to be used as an

ALL EMBEDDED

continued next page Page 1 of 2

[page 2 of 2]
adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

Preliminary Frozen Section Consultation:

Brain, left frontal mass, biopsy: Residual glioma, hold to evaluate recurrence versus progression.

Brain, left frontal tumor posterior margin, biopsy: Rule out involvement by tumor.

Gross Description:

Tissue from the brain (left frontal--5.0 x 2.5 x 2 cm, left frontal posterior margin--1.5 x 0.5 x 0.2 cm)

Block Summary:

Part A: LT.FRONTAL BRAIN TUMOR

- 1 L FRONTAL TX
- 2 L FRONTAL TX
- 3 L FRONTAL TX
- 4 L FRONTAL TX
- 5 L FRONTAL TX
- 6 L FRONTAL TX
- 7 L FRONTAL TX
- 8 L FRONTAL TX

Part B: LT.FRONTAL TUMOR POSTERIOR MARGIN

- 1 POST MG L FRONT TX

F.

ALL EMBEDDED

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 9486bf76-75eb-4de8-abe1-7af14589dd55 (TCGA-DB-5270.DD42D675-2630-4AE6-9F3B-9595DAFEE3EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).